TCGA case TCGA-DZ-6134 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e5641df6-0d4f-4613-a012-c953f8b2017e

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 69.9 years (25,529 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,856 days (5.1 years).
   Pathology details: Consistent pathology review: Yes.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Laterality: Right; Classification of tumor: Synchronous primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 430 days (1.2 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 489 days (1.3 years); Treatment anatomic sites: Locoregional Site.

Follow-up (2 entries)
- Days to follow up: 1,856 days (5.1 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DZ-6134-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-DZ-6134-01A-01-TS1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 25; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
  Slide TCGA-DZ-6134-01A-01-BS1: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-DZ-6134-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-DZ-6134-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Lyrpon.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous prostate cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,856 days; disease-specific survival: no event (censored), 1,856 days; progression-free interval: no event (censored), 1,856 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DZ-6134-01A-11D-1959-01): tumor purity 0.45, ploidy 2.15, whole-genome doublings 0.
